Somatic mutation profile of tumor specimen TCGA-GC-A4ZW-01A (aliquot TCGA-GC-A4ZW-01A-11D-A26M-08) from TCGA case TCGA-GC-A4ZW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 71.1 years (25,964 days).
Specimen TCGA-GC-A4ZW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1eee53f-3c1e-457d-bb1a-2c1e63e337e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A4ZW-10A (Blood Derived Normal), aliquot TCGA-GC-A4ZW-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5021626d-2063-43ee-86ef-276b956d5793

The open-access MAF lists 757 somatic variants for this specimen: 556 protein-altering or splice-affecting, 184 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 505, Silent 184, Nonsense Mutation 36, Intron 7, RNA 4, Splice Site 4, Frame Shift Ins 4, Splice Region 3, 5'Flank 3, 5'UTR 2, Frame Shift Del 2, In Frame Del 1.

Variants (750 of 757; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.2071C>T p.Q691* | Nonsense Mutation (SNP) | VAF 30/142 reads (21%) | catalogued as rs1555483689, COSV99268503; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSP | c.8014C>T p.Q2672* | Nonsense Mutation (SNP) | VAF 25/198 reads (13%) | catalogued as rs1064793890, COSV100672870; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 138/269 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.5710G>A p.E1904K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28933681, CM930231, COSV64270258; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.755C>G p.S252* | Nonsense Mutation (SNP) | VAF 29/153 reads (19%) | catalogued as rs267608048, CM085567, CM117499, COSV99315000; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 25/27 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1497C>G p.G499= | Splice Region (SNP) | VAF 13/54 reads (24%) | catalogued as COSV52636417; called by muse, mutect2, varscan2
- ABI2 | c.678G>C p.Q226H (on ENST00000295851 / NM_001375719.1; = p.Q220H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.605); catalogued as COSV53690314; called by muse, mutect2, varscan2
- ABI3BP | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52529920; called by muse, mutect2, varscan2
- ACACB | c.5497G>A p.A1833T | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760833780, COSV58129725; called by muse, mutect2, varscan2
- ACAD11 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as rs747513019, COSV53894178; called by muse, mutect2, varscan2
- ACE | c.2427C>G p.I809M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV52004099; called by muse, mutect2, varscan2
- ACSF3 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.043); catalogued as COSV58077018; called by muse, varscan2
- ACSL5 | c.665G>C p.R222T (on ENST00000354273; = p.R278T on NM_016234.3) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV61128622; called by muse, mutect2, varscan2
- ACTB | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as CM151362, COSV59317108; called by muse, mutect2
- ACTR8 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as COSV51634943, COSV51635317; called by muse, mutect2, varscan2
- ADA2 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV52830591; called by muse, mutect2
- ADAM21 | c.64T>A p.F22I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV50789121; called by muse, mutect2
- ADAMTS7 | c.1752C>G p.F584L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV101183009, COSV66307381; called by muse, mutect2
- ADCY8 | c.1003G>C p.G335R | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53898665; called by muse, mutect2, varscan2
- ADGRB1 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV60092778; called by muse, mutect2, varscan2
- AFF4 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV54792229; called by muse, mutect2, varscan2
- AFG1L | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64554890; called by muse, varscan2
- AKAP6 | c.5952C>G p.F1984L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55206746; called by muse, mutect2, varscan2
- AKR1B15 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV71151134, COSV71151549, COSV71151818; called by muse, mutect2, varscan2
- ALDH7A1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68628703; called by muse, mutect2, varscan2
- ANKEF1 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV65692030; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV51841761; called by muse, mutect2, varscan2
- ANKRD17 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58216390; called by muse, mutect2, varscan2
- ANKRD23 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as COSV100450313; called by muse, mutect2
- AP3B1 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54877429; called by muse, mutect2, varscan2
- APBB1IP | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 15/145 reads (10%) | catalogued as COSV100774288, COSV63304588; called by muse, mutect2, varscan2
- APLF | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV58143116; called by muse, mutect2, varscan2
- APOB | c.10484C>G p.S3495C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51926105; called by muse, mutect2, varscan2
- AQP2 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV52229205; called by muse, mutect2, varscan2
- ARAP2 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs760700898, COSV58283536; called by muse, mutect2, varscan2
- ARHGAP28 | c.923C>G p.S308* (on ENST00000383472 / NM_001366230.1; = p.S149* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV51635370, COSV99148434; called by muse, mutect2, varscan2
- ARHGAP35 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68329566; called by muse, mutect2, varscan2
- ARHGAP5 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61534215, COSV61539084; called by muse, mutect2, varscan2
- ARHGEF40 | c.3538G>C p.E1180Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); catalogued as COSV53878667; called by muse, mutect2
- ARID1A | c.4330G>C p.E1444Q | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV61371713, COSV61372913; called by muse, mutect2, varscan2
- ASTN2 | c.3733G>A p.E1245K (on ENST00000313400 / NM_001365069.1; = p.E1194K on NM_014010.5) | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV56000282; called by muse, mutect2, varscan2
- ASXL2 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.143); catalogued as COSV55454714, COSV55456647, COSV99710306; called by muse, mutect2, varscan2
- ASXL2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55454728; called by muse, mutect2, varscan2
- ATP10A | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs754770410, COSV63514430; called by muse, mutect2, varscan2
- ATP7B | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54435872; called by muse, mutect2, varscan2
- ATR | c.7809C>G p.I2603M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53808775; called by muse, mutect2, varscan2
- AVIL | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749386081, COSV57680754; called by muse, mutect2, varscan2
- B3GNT2 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 57/414 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV57344059; called by muse, mutect2, varscan2
- B4GALT4 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV63295569, COSV63296093; called by muse, mutect2, varscan2
- BAAT | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV52287513; called by muse, mutect2, varscan2
- BAZ1B | c.3495G>A p.M1165I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV59989198; called by muse, mutect2, varscan2
- BEND5 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65716511, COSV65716676; called by mutect2, varscan2
- BORCS6 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV66504784; called by muse, mutect2, varscan2
- BRAT1 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1181302197, COSV100500375, COSV61394410; called by muse, mutect2
- BRPF3 | c.2717G>A p.R906K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV60206344; called by muse, mutect2, varscan2
- BSN | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV56513924; called by muse, varscan2
- BSN | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56513933; called by muse, varscan2
- BST1 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as rs776580177, COSV99399779; called by muse, mutect2, varscan2
- BTBD3 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV54778138, COSV54780790, COSV99655568; called by muse, mutect2, varscan2
- BTK | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV58117740; called by muse, mutect2, varscan2
- C12orf66 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV61322535; called by muse, mutect2, varscan2
- C18orf21 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV99321536; called by muse, mutect2
- CACNA1G | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.383); catalogued as rs60039322, COSV61721180; called by muse, mutect2, varscan2
- CAP2 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV57730521; called by muse, mutect2, varscan2
- CASQ2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54768086; called by muse, mutect2, varscan2
- CCDC18 | c.2476G>C p.E826Q (on ENST00000343253 / NM_001306076.1; = p.E827Q on NM_206886.4) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV58141660; called by muse, mutect2, varscan2
- CCDC33 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs757090698, COSV58347636, COSV58348905; called by muse, varscan2
- CCDC42 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV53448127, COSV53449071; called by muse, mutect2, varscan2
- CCDC47 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV56722090; called by muse, mutect2, varscan2
- CCDC65 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV56739223; called by muse, mutect2, varscan2
- CCL20 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100721773; called by muse, mutect2
- CCNY | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs556153316, COSV55182111; called by muse, mutect2, varscan2
- CD22 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV50049919; called by muse, mutect2, varscan2
- CD5L | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.076); catalogued as COSV63821273; called by muse, mutect2, varscan2
- CD81 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144435973; called by muse, mutect2, varscan2
- CDC6 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV52929897; called by muse, mutect2, varscan2
- CDH11 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51753294; called by muse, mutect2, varscan2
- CDHR1 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1462875173, COSV60560072; called by muse, mutect2, varscan2
- CDYL2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs376407812; called by mutect2, varscan2
- CELA2A | c.492G>A p.Q164= | Splice Region (SNP) | VAF 13/129 reads (10%) | catalogued as COSV100657489; called by muse, mutect2, varscan2
- CELSR3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770585899, COSV50841296, COSV50842619; called by muse, mutect2, varscan2
- CENPB | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV60144760; called by muse, mutect2, varscan2
- CENPC | c.1816C>G p.H606D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV56621532; called by muse, mutect2, varscan2
- CENPE | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs1216546462, COSV54377119; called by muse, mutect2, varscan2
- CEP44 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99639182; called by muse, mutect2
- CEP95 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.267); catalogued as COSV73608747; called by muse, mutect2, varscan2
- CFH | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as COSV66406397; called by muse, mutect2, varscan2
- CHD3 | c.5630C>T p.A1877V (on ENST00000330494 / NM_001005273.3; = p.A1843V on NM_005852.4) | Missense Mutation (SNP) | VAF 89/104 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57873113; called by muse, mutect2, varscan2
- CHL1 | c.2888G>A p.G963E (on ENST00000397491 / NM_001253387.1; = p.G979E on NM_006614.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.363); catalogued as COSV56588021; called by muse, mutect2
- CHMP1B | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV52324175; called by muse, mutect2, varscan2
- CIAO2B | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57696368; called by muse, mutect2, varscan2
- CIZ1 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.81); catalogued as COSV52970459, COSV99476617; called by muse, mutect2, varscan2
- CLSPN | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.415); catalogued as COSV52047613; called by muse, mutect2, varscan2
- CLTC | c.1843C>A p.Q615K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV52245431; called by muse, mutect2, varscan2
- CNTN4 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61868999; called by muse, mutect2, varscan2
- COPA | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54098957; called by muse, mutect2, varscan2
- COQ5 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs752994991, COSV56018476; called by muse, mutect2, varscan2
- CORIN | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs763680668, COSV56687603; called by muse, mutect2, varscan2
- CPVL | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761025460, COSV55299812, COSV55301014; called by muse, mutect2, varscan2
- CRAMP1 | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV51960195; called by muse, mutect2, varscan2
- CRYBA1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56600493, COSV99837060; called by muse, mutect2, varscan2
- CSDE1 | c.1070G>A p.R357K (on ENST00000358528 / NM_001007553.3; = p.R326K on NM_007158.6) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV54740395; called by muse, mutect2, varscan2
- CSPG5 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53130294; called by muse, mutect2, varscan2
- CSPP1 | c.2436G>C p.Q812H (on ENST00000676605; = p.Q771H on NM_024790.6) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51581018; called by muse, mutect2, varscan2
- CSTF2T | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV58656034; called by muse, mutect2, varscan2
- CTSC | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV57056622; called by muse, mutect2, varscan2
- CTXN1 | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54490379; called by muse, mutect2, varscan2
- CUBN | c.5830C>G p.H1944D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100913854, COSV64709348; called by muse, mutect2, varscan2
- CYC1 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59643992; called by muse, mutect2, varscan2
- CYP2S1 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.157); catalogued as COSV59505236; called by muse, mutect2, varscan2
- CYP3A43 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55935263; called by muse, mutect2, varscan2
- CYSLTR2 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV56165320; called by muse, mutect2, varscan2
- DAAM1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62834558, COSV62840318; called by muse, mutect2, varscan2
- DACH1 | c.1900G>C p.D634H (on ENST00000619232 / NM_001366712.1; = p.D380H on NM_004392.6) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57491678; called by muse, mutect2, varscan2
- DCBLD2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100471367, COSV58791866; called by muse, mutect2
- DDX10 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59432122; called by muse, mutect2, varscan2
- DHX36 | c.2794G>C p.E932Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV57671244; called by muse, mutect2, varscan2
- DISP3 | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs1436532178, COSV53821944; called by muse, mutect2, varscan2
- DLD | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV52737078; called by muse, mutect2, varscan2
- DNAAF5 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV52414600, COSV99860278; called by muse, mutect2, varscan2
- DNAH2 | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); catalogued as rs199664791, COSV66717280; called by muse, mutect2, varscan2
- DNAH5 | c.13034C>G p.S4345C | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54208620, COSV54249423; called by muse, mutect2
- DNAI2 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs368063114; called by muse, mutect2, varscan2
- DNMBP | c.2129G>C p.R710T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV60621556; called by muse, mutect2, varscan2
- DOCK10 | c.3222G>C p.K1074N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.297); catalogued as COSV51354203; called by muse, varscan2
- DOCK8 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV66633016; called by muse, mutect2, varscan2
- DPH2 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV52542737, COSV99356213; called by muse, mutect2, varscan2
- DPP10 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV59669036; called by muse, mutect2
- DSP | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.844); catalogued as COSV65791543; called by muse, mutect2, varscan2
- DSP | c.7579C>G p.Q2527E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV65791547; called by muse, mutect2, varscan2
- DTX3 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV54084849; called by muse, mutect2, varscan2
- DUSP29 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV58300107; called by muse, mutect2, varscan2
- E2F7 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV59737969; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1216G>T p.D406Y (on ENST00000361735 / NM_015935.5; = p.D320Y on NM_014955.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV62282579; called by muse, mutect2, varscan2
- EEF2K | c.1261A>G p.M421V | Missense Mutation (SNP) | VAF 41/416 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs576069878, COSV53779316; called by muse, mutect2, varscan2
- EGF | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV54476391; called by muse, mutect2, varscan2
- EHMT1 | c.3742G>C p.D1248H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV101134985; called by muse, mutect2
- EIF4A1 | c.1153C>G p.R385G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV51510033, COSV51511514; called by muse, mutect2, varscan2
- EIF4G2 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746458672, COSV60596336, COSV60598957; called by muse, mutect2, varscan2
- ELAPOR1 | c.2825C>G p.S942C | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64040362, COSV64041221; called by muse, mutect2
- ELF3 | c.1052_1054del p.V351_Y352delinsD | In Frame Del (DEL) | VAF 50/86 reads (58%) | catalogued as COSV62837447; called by mutect2, pindel, varscan2
- ELF4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 110/120 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57451686; called by muse, mutect2, varscan2
- ELOVL6 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56427437; called by muse, mutect2, varscan2
- ELP1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV59828867, COSV59828942; called by muse, mutect2, varscan2
- EMILIN2 | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.627); catalogued as COSV54421635, COSV54426073; called by muse, mutect2, varscan2
- EMILIN2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54421647; called by muse, mutect2
- ENPP5 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs375181447; called by muse, mutect2, varscan2
- EOMES | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55411414; called by muse, mutect2, varscan2
- EPHB2 | c.2202G>T p.M734I (on ENST00000400191 / NM_001309193.2; = p.M735I on NM_004442.7) | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101007124, COSV65860383; called by muse, mutect2
- EPSTI1 | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV58044248; called by muse, mutect2, varscan2
- ERBB2 | c.1958C>G p.S653C | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV54064732, COSV99507322; called by muse, mutect2, varscan2
- ERCC6 | c.4051G>C p.E1351Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV63388265; called by muse, mutect2, varscan2
- ERCC6 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV63388270; called by muse, mutect2, varscan2
- ESCO1 | c.2458A>G p.T820A | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52518654; called by muse, mutect2, varscan2
- ESPL1 | c.3716C>G p.S1239* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | catalogued as COSV99228880; called by muse, mutect2, varscan2
- EXOSC10 | c.2393G>A p.R798Q (on ENST00000376936 / NM_001001998.3; = p.R773Q on NM_002685.4) | Missense Mutation (SNP) | VAF 86/699 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV58664077; called by muse, mutect2, varscan2
- EXTL1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs544501118, COSV100959049; called by muse, mutect2, varscan2
- EYA4 | c.1117G>A p.D373N (on ENST00000531901 / NM_001301013.1; = p.D367N on NM_004100.5) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as rs866788038, COSV62046968; called by muse, mutect2, varscan2
- F11 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53004592; called by muse, mutect2, varscan2
- FAM160A2 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV56409987; called by muse, mutect2, varscan2
- FAM170A | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV58924238; called by muse, mutect2, varscan2
- FAM217A | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1305193206, COSV51159058; called by muse, mutect2, varscan2
- FAM3A | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs782379297, COSV59194149; called by muse, mutect2, varscan2
- FAM47C | c.2468A>G p.H823R | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.674); catalogued as COSV63724341; called by muse, mutect2, varscan2
- FAM78B | c.331A>C p.S111R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.986); catalogued as COSV57975596; called by muse, mutect2, varscan2
- FAT3 | c.7361C>G p.S2454C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53083567; called by muse, mutect2, varscan2
- FAT4 | c.13898C>G p.S4633W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58674300, COSV58674409; called by mutect2, varscan2
- FBXL4 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 81/88 reads (92%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs933323574, COSV57745345; called by muse, mutect2, varscan2
- FBXO34 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1344613059, COSV58253599; called by muse, mutect2, varscan2
- FCRL1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as rs935262369, COSV63824131; called by muse, mutect2, varscan2
- FCRL4 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138667797, COSV54860343, COSV54863078; called by muse, mutect2, varscan2
- FGFRL1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as rs200852436, COSV99294897; called by muse, mutect2, varscan2
- FN1 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.809); catalogued as rs573992192, COSV60547894; called by muse, mutect2, varscan2
- FNDC3A | c.1938G>C p.Q646H (on ENST00000492622 / NM_001079673.2; = p.Q590H on NM_014923.5) | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as COSV68132439, COSV68135121; called by muse, mutect2
- FPR2 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as COSV60672087; called by muse, mutect2, varscan2
- FRMD3 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.028); catalogued as rs367902496; called by muse, mutect2, varscan2
- FYTTD1 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs773349004, COSV54082320; called by muse, mutect2, varscan2
- GADL1 | c.1419G>A p.M473I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56975839; called by muse, mutect2, varscan2
- GALNTL6 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.268); catalogued as COSV101560095; called by muse, mutect2
- GCLC | c.133G>A p.D45N (on ENST00000643939; = p.D49N on NM_001498.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV57593947; called by muse, mutect2, varscan2
- GCN1 | c.6545C>T p.S2182L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV56104726; called by muse, mutect2, varscan2
- GDF5 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.538); catalogued as COSV65499809; called by muse, mutect2, varscan2
- GDNF | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58478548; called by muse, mutect2, varscan2
- GEMIN5 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); catalogued as rs778521161, COSV53558709; called by muse, mutect2, varscan2
- GJA9 | c.1341C>G p.F447L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV62531859; called by muse, mutect2, varscan2
- GLOD4 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56752603; called by muse, mutect2, varscan2
- GLUD2 | c.951G>C p.M317I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as COSV60151464; called by muse, mutect2, varscan2
- GMPPB | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV57537743; called by muse, mutect2, varscan2
- GNRH2 | c.362G>C p.*121Sext*? | Nonstop Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99848588; called by muse, mutect2, varscan2
- GOLGA2 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV68596982; called by muse, mutect2, varscan2
- GOLGA5 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV50832222; called by muse, mutect2, varscan2
- GOLGB1 | c.6722G>C p.R2241T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as COSV61462510; called by muse, mutect2, varscan2
- GPR1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV67976514; called by muse, mutect2
- GPR32 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1568459841, COSV54513884; called by muse, mutect2, varscan2
- GPR63 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57739904; called by muse, mutect2, varscan2
- GPR75 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as rs377062100; called by muse, mutect2, varscan2
- GPR75 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV61825330; called by muse, mutect2, varscan2
- GPRASP1 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV64354960; called by muse, mutect2, varscan2
- GRB7 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58446606; called by muse, mutect2
- GRIA2 | c.2550G>C p.K850N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as COSV52384222, COSV52384723, COSV99642831; called by muse, mutect2, varscan2
- GRM1 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51113002; called by muse, mutect2, varscan2
- GRTP1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58148901; called by muse, mutect2, varscan2
- GSC | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1297615827, COSV53076792; called by muse, mutect2, varscan2
- GSTA1 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as COSV58014690; called by muse, mutect2, varscan2
- H2AC16 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.618); catalogued as COSV58899243; called by muse, mutect2, varscan2
- H2AZ2 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV56062110; called by muse, mutect2, varscan2
- HCN1 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57496844; called by muse, mutect2
- HDAC4 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61860776; called by muse, mutect2, varscan2
- HENMT1 | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1303907047, COSV64229962; called by muse, mutect2, varscan2
- HERC2 | c.3904C>G p.L1302V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55311405; called by muse, mutect2, varscan2
- HIC2 | c.1475C>G p.S492* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101335530, COSV68041805; called by muse, mutect2, varscan2
- HIVEP2 | c.4111G>C p.E1371Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV50006322; called by muse, mutect2, varscan2
- HMGCS2 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65567380; called by muse, mutect2, varscan2
- HNRNPR | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 31/212 reads (15%) | catalogued as COSV100164307, COSV100164684; called by muse, mutect2, varscan2
- HOMER3 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55355018, COSV55357893; called by muse, mutect2, varscan2
- HS3ST2 | c.486G>C p.R162S | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54459014; called by muse, mutect2
- HS6ST3 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as COSV65003596; called by muse, mutect2, varscan2
- IDO1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53713218; called by muse, mutect2, varscan2
- IDS | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as COSV61711475, COSV61713425; called by muse, mutect2
- IFI35 | c.765C>A p.F255L (on ENST00000415816 / NM_001330230.2; = p.F257L on NM_005533.5) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55895974; called by muse, mutect2, varscan2
- IGF2BP2 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV60483791; called by muse, mutect2, varscan2
- INSR | c.2152C>G p.Q718E | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57158843; called by muse, mutect2, varscan2
- INTS6L | c.2147C>G p.S716C | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV100878012; called by muse, mutect2
- IRS4 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as COSV64532879; called by muse, mutect2, varscan2
- ITPA | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as COSV101200050; called by muse, mutect2, varscan2
- JAK3 | c.3014C>G p.S1005C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV71685751, COSV71685804; called by muse, mutect2, varscan2
- JAZF1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.969); catalogued as COSV52233652; called by muse, mutect2, varscan2
- KATNA1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs149685408; called by muse, mutect2, varscan2
- KATNIP | c.2997C>G p.F999L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55174944; called by muse, mutect2, varscan2
- KCNB2 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV73049210; called by muse, mutect2, varscan2
- KCNH3 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99234698; called by mutect2, varscan2
- KCNJ5 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253531265, COSV57963804, COSV57966506; called by muse, mutect2, varscan2
- KCTD17 | c.862C>T p.R288W (on ENST00000403888 / NM_001282684.1; = p.R264W on NM_024681.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs746903628, COSV60975679; called by muse, mutect2
- KDM3B | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 150/181 reads (83%) | catalogued as COSV100069155; called by muse, mutect2, varscan2
- KIAA0319L | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57842883; called by muse, mutect2, varscan2
- KIAA1841 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.591); catalogued as COSV54373159; called by muse, mutect2, varscan2
- KIF1B | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55804484; called by muse, mutect2
- KIF1B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV55804499; called by muse, mutect2, varscan2
- KIF5B | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56651291; called by mutect2, varscan2
- KIFC1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV65737370; called by muse, mutect2, varscan2
- KLB | c.1091G>C p.R364T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV57300440, COSV57300613; called by muse, mutect2, varscan2
- KLHL1 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.237); catalogued as COSV64767985; called by muse, mutect2
- KLHL32 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV100987120; called by muse, mutect2
- KRT2 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.942); catalogued as rs1407901940, COSV100548282; called by muse, mutect2, varscan2
- KRT81 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100576908; called by muse, mutect2, varscan2
- LAIR2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); catalogued as COSV56620946; called by muse, mutect2, varscan2
- LAPTM4A | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.672); catalogued as COSV51531989; called by muse, mutect2, varscan2
- LARGE1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61658633; called by muse, mutect2, varscan2
- LATS2 | c.2979C>G p.I993M | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66873899; called by muse, mutect2
- LDLRAD1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420418564, COSV64955798, COSV64955808; called by muse, mutect2, varscan2
- LDLRAD4 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63334432; called by muse, mutect2, varscan2
- LETMD1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1440634026, COSV50396658; called by muse, mutect2, varscan2
- LGMN | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV58402951; called by muse, mutect2
- LHX2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV101010021; called by muse, mutect2
- LILRB2 | c.1667C>G p.A556G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV58743854; called by muse, mutect2, varscan2
- LIMCH1 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.352); catalogued as rs1355904486, COSV58275858; called by muse, mutect2, varscan2
- LINGO3 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1165694904, COSV68261023; called by muse, mutect2, varscan2
- LLGL2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs1188980168, COSV51342714; called by muse, mutect2, varscan2
- LMAN2 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57424202, COSV57424360; called by mutect2, varscan2
- LPA | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 91/436 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100306039; called by muse, mutect2, varscan2
- LRATD2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs780491494, COSV59229842, COSV59229849; called by muse, mutect2, varscan2
- LRIF1 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV63896793; called by muse, mutect2
- LRP1B | c.10034G>C p.G3345A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.817); catalogued as COSV67193530; called by muse, mutect2, varscan2
- LRRC37A3 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV59760394; called by mutect2, varscan2
- LRRK2 | c.3171G>C p.M1057I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs200663116, COSV54146264; called by muse, mutect2, varscan2
- MAGEC1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 318/325 reads (98%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.641); catalogued as rs1248359822, COSV53567287; called by muse, mutect2, varscan2
- MAGEC1 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 80/1514 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV53569129, COSV53574680; called by muse, mutect2
- MAGEC3 | c.275C>G p.S92* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100024804, COSV71610092; called by muse, mutect2
- MAP1B | c.5515G>A p.D1839N | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.32); catalogued as rs754067983, COSV57094967; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61009816; called by muse, mutect2, varscan2
- MAP2K6 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV63005207; called by muse, varscan2
- MAP3K5 | c.2369G>C p.G790A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV62887554; called by muse, mutect2
- MAP3K8 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV53918890; called by muse, mutect2, varscan2
- MATN2 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV54707666, COSV99646842; called by muse, mutect2, varscan2
- MCHR1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1355975109, COSV50760453; called by muse, mutect2, varscan2
- MCMBP | c.1488G>C p.Q496H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs757642718, COSV63508634; called by muse, mutect2, varscan2
- MED1 | c.915G>C p.L305F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV56122827, COSV56126326; called by muse, mutect2
- MED11 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.808); catalogued as COSV99543385; called by muse, mutect2
- MET | c.2290G>C p.G764R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100576995; called by muse, mutect2
- MMRN1 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV53334548; called by muse, mutect2, varscan2
- MMRN1 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53334562, COSV53343126; called by muse, mutect2, varscan2
- MNDA | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV63740094; called by muse, mutect2, varscan2
- MRM3 | c.998G>C p.W333S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV58679388; called by muse, mutect2, varscan2
- MRPL34 | c.145C>A p.R49S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV99395435; called by muse, varscan2
- MRPL40 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54272956; called by muse, mutect2
- MRPL55 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs765181332, COSV54341911; called by muse, mutect2, varscan2
- MRPS35 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762062628, COSV50011197, COSV50012641; called by muse, mutect2, varscan2
- MTA3 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68133014; called by muse, mutect2, varscan2
- MTF2 | c.1343C>G p.S448* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100940053, COSV100940228; called by muse, mutect2, varscan2
- MTG2 | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV63693452; called by muse, mutect2, varscan2
- MUC16 | c.34757C>G p.T11586R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.18); catalogued as COSV67450327; called by muse, mutect2, varscan2
- MXRA7 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | PolyPhen benign (0.442); catalogued as rs1393149219, COSV63320729; called by muse, mutect2, varscan2
- MYH14 | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV51811712; called by muse, mutect2, varscan2
- MYH3 | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56861811; called by muse, mutect2, varscan2
- MYH4 | c.2137T>C p.F713L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV55113651; called by muse, mutect2, varscan2
- MYH7 | c.4015G>C p.D1339H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62516984; called by muse, mutect2, varscan2
- MYO5A | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62557206; called by muse, mutect2, varscan2
- MYPN | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs869025490, COSV62731989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAE1 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV51975239; called by muse, mutect2
- NALCN | c.3774G>A p.M1258I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as COSV51921702; called by muse, mutect2, varscan2
- NCDN | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as COSV57842897; called by muse, mutect2
- NCOR1 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99247063; called by muse, mutect2, varscan2
- NEK11 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs376755010; called by muse, mutect2, varscan2
- NFASC | c.2392G>C p.E798Q (on ENST00000339876 / NM_001378329.1; = p.E794Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV58360452; called by muse, mutect2, varscan2
- NFATC4 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as rs775629255, COSV51597418, COSV51600105; called by muse, mutect2, varscan2
- NID1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99936959; called by muse, mutect2, varscan2
- NIFK | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99590536, COSV99590685; called by muse, mutect2
- NIN | c.6046G>A p.E2016K (on ENST00000382041 / NM_182946.1; = p.E1303K on NM_016350.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV55382264, COSV55394523; called by muse, mutect2, varscan2
- NIN | c.4528G>C p.E1510Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.623); catalogued as COSV55382285; called by muse, mutect2, varscan2
- NKIRAS2 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs782245281, COSV56917497; called by muse, mutect2, varscan2
- NLN | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV66765100, COSV66766630; called by muse, mutect2, varscan2
- NRP1 | c.1937A>G p.Y646C | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as rs770248476, COSV55161247; called by muse, mutect2, varscan2
- NSD3 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs761714577, COSV57617580; called by muse, mutect2
- NSRP1 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.513); catalogued as COSV55933144; called by muse, mutect2, varscan2
- NUP133 | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54568824; called by muse, mutect2, varscan2
- NUP210 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54403284; called by muse, mutect2
- OBSCN | c.3629C>G p.S1210* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV99472314; called by muse, mutect2, varscan2
- OPTC | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65867242, COSV65867334; called by muse, mutect2, varscan2
- OR4A15 | c.191T>C p.L64S | Missense Mutation (SNP) | VAF 64/73 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59033874; called by muse, mutect2, varscan2
- OR5AC2 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as COSV62279218, COSV62279606; called by muse, mutect2, varscan2
- OXLD1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1187408333, COSV61303033; called by muse, mutect2, varscan2
- PALB2 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV55162927, COSV55166885; called by muse, mutect2, varscan2
- PAPOLG | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV53181579; called by muse, mutect2, varscan2
- PARP9 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100830893; called by muse, mutect2, varscan2
- PAX9 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); catalogued as COSV58716461; called by muse, mutect2, varscan2
- PCDH15 | c.4577dup p.N1526Kfs*278 (on ENST00000617271 / NM_001142770.3; = p.P1515Tfs*4 on NM_001142769.3) | Frame Shift Ins (INS) | VAF 14/117 reads (12%) | catalogued as rs1554815895; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- PCDH17 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV100931422; called by muse, mutect2, varscan2
- PCDH9 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV60532834; called by muse, mutect2, varscan2
- PCDHA1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as COSV65372967; called by muse, mutect2, varscan2
- PCDHB3 | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV50589285, COSV99164152; called by muse, mutect2, varscan2
- PCDHGA5 | c.1800G>C p.Q600H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV53910001; called by muse, mutect2, varscan2
- PDHB | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240039; called by muse, mutect2
- PDHX | c.999C>G p.I333M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57164502; called by muse, mutect2
- PGBD1 | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV52551641; called by muse, mutect2, varscan2
- PGLYRP4 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1200175709, COSV62834724, COSV62836012; called by muse, mutect2, varscan2
- PGM1 | c.1221G>C p.Q407H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV64300138; called by muse, mutect2
- PHACTR2 | c.813C>G p.D271E | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs769251687, COSV59851168; called by muse, mutect2, varscan2
- PICK1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs751138380, COSV63659653; called by muse, mutect2
- PIGG | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV56316581; called by muse, mutect2, varscan2
- PINX1 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV100134659; called by muse, mutect2
- PKDREJ | c.4535C>T p.S1512F | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV53547044; called by muse, mutect2, varscan2
- PKHD1L1 | c.9949C>G p.P3317A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV65738754; called by muse, mutect2, varscan2
- PLAAT1 | c.316-1G>A p.X106_splice (on ENST00000650797; = p.X1_splice on NM_020386.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as COSV53230293; called by muse, mutect2, varscan2
- PLCL2 | c.1710G>C p.K570N (on ENST00000615277 / NM_001144382.2; = p.K444N on NM_015184.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67620955; called by muse, varscan2
- PLCL2 | c.1753G>A p.D585N (on ENST00000615277 / NM_001144382.2; = p.D459N on NM_015184.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as COSV101196559; called by muse, varscan2
- PLEKHG5 | c.922G>C p.E308Q (on ENST00000400915 / NM_001042663.3; = p.E271Q on NM_020631.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV61700324; called by muse, mutect2, varscan2
- PNCK | c.689A>G p.E230G (on ENST00000340888 / NM_001366975.1; = p.E313G on NM_001039582.3) | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61742769; called by muse, mutect2, varscan2
- POLD1 | c.2342G>A p.W781* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs1434951609, COSV101486752; called by muse, mutect2, varscan2
- POLR3A | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64930429; called by muse, mutect2, varscan2
- PPARG | c.382G>A p.E128K (on ENST00000287820 / NM_015869.5; = p.E98K on NM_005037.7) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV99826286; called by muse, mutect2
- PPAT | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51703258, COSV99947291; called by muse, mutect2, varscan2
- PPRC1 | c.4856G>A p.R1619Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs1228081662, COSV53383618, COSV53387430; called by muse, mutect2, varscan2
- PPWD1 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54332859; called by muse, mutect2, varscan2
- PRDM16 | c.2347A>G p.K783E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV54581291; called by muse, mutect2
- PRMT1 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV67159265; called by muse, mutect2, varscan2
- PRORP | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV51616226; called by muse, mutect2, varscan2
- PRR30 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 81/153 reads (53%) | catalogued as rs1011662920, COSV99574294; called by muse, mutect2, varscan2
- PRR7 | c.42C>G p.F14L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV52787983; called by muse, mutect2, varscan2
- PSAPL1 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV59842463; called by muse, varscan2
- PSMB4 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1241669036, COSV51850341, COSV51850597; called by muse, mutect2, varscan2
- PTPRG | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.57); catalogued as COSV55631538; called by muse, mutect2, varscan2
- PUS7L | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV61261350; called by muse, mutect2
- QPCT | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58119196; called by muse, mutect2, varscan2
- QRFP | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58064736; called by muse, mutect2, varscan2
- QSER1 | c.5092G>T p.E1698* (on ENST00000399302; = p.E1827* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV101234632; called by muse, mutect2, varscan2
- RAD17 | c.265G>A p.E89K (on ENST00000380774 / NM_133339.2; = p.E78K on NM_002873.1) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV51456438; called by muse, mutect2, varscan2
- RAD51D | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1285339297, COSV60004006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD54L2 | c.1143G>A p.K381= | Splice Region (SNP) | VAF 5/38 reads (13%) | catalogued as rs1364090479, COSV56577374; called by muse, mutect2, varscan2
- RAI14 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 10/226 reads (4%) | catalogued as COSV99461848; called by muse, mutect2
- RALGAPA2 | c.5396G>C p.G1799A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52490485; called by muse, mutect2, varscan2
- RASA1 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV57192107, COSV57195433; called by muse, varscan2
- RB1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99923053; called by muse, mutect2, varscan2
- RBM19 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99925481; called by muse, mutect2, varscan2
- RDH16 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62457951; called by muse, mutect2, varscan2
- REV3L | c.3646G>C p.E1216Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV100724841; called by muse, mutect2
- RHBG | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54802408; called by muse, mutect2, varscan2
- RICTOR | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.435); catalogued as COSV57118295; called by muse, mutect2
- RNASEL | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV62376328; called by muse, mutect2, varscan2
- RNF17 | c.3035G>C p.R1012T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55035442, COSV55040176; called by muse, mutect2, varscan2
- RPP38 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1443309492, COSV65381580; called by muse, mutect2
- RPRD1A | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV61360739; called by muse, mutect2, varscan2
- RTCA | c.711C>G p.D237E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV53119637; called by muse, mutect2
- RTL8C | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 21/405 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.41); catalogued as COSV57059677; called by muse, mutect2
- RTP1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as COSV56617885; called by muse, mutect2
- RUSF1 | c.861G>C p.L287F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.162); catalogued as COSV57890397; called by muse, mutect2, varscan2
- SAAL1 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100253723; called by muse, mutect2
- SACS | c.12757C>G p.Q4253E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV66535764; called by muse, mutect2, varscan2
- SACS | c.4844C>T p.P1615L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as rs1185308440, COSV66535787; called by muse, mutect2, varscan2
- SBNO2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62318907; called by muse, mutect2
- SCAP | c.3382G>A p.D1128N | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55543007; called by muse, mutect2, varscan2
- SCN10A | c.4260C>G p.N1420K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71860513, COSV71861794; called by muse, mutect2, varscan2
- SCN7A | c.4825T>A p.F1609I | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV69269423; called by muse, mutect2, varscan2
- SCRIB | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583103; called by muse, mutect2, varscan2
- SERINC3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs774380356, COSV54855641; called by muse, mutect2, varscan2
- SERPINC1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV62928965; called by muse, mutect2, varscan2
- SESN3 | c.325C>G p.H109D | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53583607; called by muse, mutect2, varscan2
- SEZ6L | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV50658915, COSV50679684; called by muse, mutect2, varscan2
- SFPQ | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV61758348, COSV61758934; called by muse, mutect2, varscan2
- SGIP1 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV52763100; called by muse, mutect2
- SH3BP2 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62553660; called by muse, mutect2, varscan2
- SHD | c.773A>T p.K258M | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1343043290, COSV56666185; called by muse, varscan2
- SHQ1 | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV57764266; called by muse, mutect2, varscan2
- SIGLEC12 | c.881C>G p.S294C (on ENST00000291707 / NM_053003.4; = p.S176C on NM_033329.2) | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52459906; called by muse, mutect2, varscan2
- SIRT4 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV52540507, COSV99177386; called by muse, varscan2
- SIRT4 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52540202; called by muse, varscan2
- SIRT4 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52540210, COSV52541220, COSV52541762; called by muse, mutect2, varscan2
- SLC26A9 | c.1352A>C p.D451A | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61601209; called by muse, mutect2, varscan2
- SLC2A2 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV58584934; called by muse, mutect2, varscan2
- SLC2A9 | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV53317460; called by muse, mutect2, varscan2
- SLC38A2 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV56744269; called by muse, mutect2, varscan2
- SLC41A3 | c.1103C>G p.S368* | Nonsense Mutation (SNP) | VAF 18/224 reads (8%) | catalogued as COSV100259340; called by muse, mutect2
- SLC4A4 | c.608A>G p.K203R (on ENST00000264485 / NM_001098484.3; = p.K159R on NM_003759.4) | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.068); catalogued as COSV52616770; called by muse, mutect2, varscan2
- SLC5A3 | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.407); catalogued as COSV62968349; called by muse, mutect2, varscan2
- SLCO1B1 | c.1889C>G p.S630* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99917975; called by muse, mutect2, varscan2
- SMARCAL1 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs1465106642, COSV61920152; called by muse, mutect2, varscan2
- SMC2 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs781477090, COSV53955720; called by muse, mutect2, varscan2
- SMC6 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as rs751244792, COSV100704760; called by muse, mutect2, varscan2
- SMC6 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV61171945; called by muse, mutect2, varscan2
- SNAP91 | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52118089, COSV99534313, COSV99534578; called by muse, mutect2
- SNAPC3 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV66460003; called by muse, mutect2, varscan2
- SNRNP70 | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55505133; called by muse, mutect2, varscan2
- SNTA1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1327460672, COSV54128460; called by muse, mutect2, varscan2
- SORT1 | c.1037G>C p.G346A | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV56664753; called by muse, mutect2, varscan2
- SOX5 | c.1023A>C p.L341F | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100508736, COSV58621020, COSV58637081; called by muse, mutect2, varscan2
- SOX8 | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53508879; called by muse, mutect2
- SPAG17 | c.2426C>G p.S809C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60454158; called by muse, mutect2, varscan2
- SPAG4 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV65330074; called by muse, mutect2, varscan2
- SPATA18 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99729972; called by muse, mutect2
- SPATA5 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV56772852; called by muse, mutect2
- SPEF2 | c.4074T>G p.F1358L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV61545059; called by muse, mutect2, varscan2
- SPHKAP | c.4132G>T p.E1378* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100763675; called by muse, mutect2, varscan2
- SPIN2A | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV66520316, COSV66520671; called by muse, mutect2, varscan2
- SPTBN1 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61686215; called by muse, mutect2
- SRC | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100657992, COSV62439343; called by muse, mutect2, varscan2
- SRGAP1 | c.1676G>A p.R559K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.672); catalogued as COSV61895080; called by muse, mutect2
- STAB2 | c.7019G>A p.R2340Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs142853959, COSV66335424; called by muse, mutect2, varscan2
- STAB2 | c.7267G>A p.D2423N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.354); catalogued as COSV66335428; called by muse, mutect2
- STAG1 | c.444C>G p.I148M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); catalogued as COSV52603369; called by muse, mutect2, varscan2
- STARD13 | c.2230G>C p.E744Q (on ENST00000336934 / NM_001243476.3; = p.E626Q on NM_052851.3) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55228004; called by muse, mutect2, varscan2
- SUFU | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV64017277; called by muse, mutect2, varscan2
- SUPT6H | c.2698G>C p.E900Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV58925155; called by muse, mutect2, varscan2
- SYCP1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as COSV101050745; called by muse, mutect2
- SYCP2 | c.4408A>G p.K1470E | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV62766487; called by muse, mutect2, varscan2
- SYNE1 | c.8727G>C p.Q2909H (on ENST00000367255 / NM_182961.4; = p.Q2916H on NM_033071.3) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV54922787; called by muse, mutect2, varscan2
- TAAR1 | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51587832; called by muse, mutect2, varscan2
- TAAR2 | c.615C>G p.F205L (on ENST00000367931 / NM_001033080.1; = p.F160L on NM_014626.3) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51578527; called by muse, mutect2, varscan2
- TACC2 | c.4982G>C p.R1661T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs372221128; called by muse, mutect2, varscan2
- TAF1L | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV54258843, COSV54259777; called by muse, mutect2, varscan2
- TAL2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61883671; called by muse, mutect2, varscan2
- TARS1 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV54307793; called by muse, mutect2
- TAS2R40 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV101283021, COSV68818172; called by muse, mutect2, varscan2
- TAS2R42 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62084417; called by mutect2, varscan2
- TBC1D16 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60475939; called by muse, mutect2
- TBX3 | c.1038C>G p.F346L (on ENST00000257566 / NM_016569.4; = p.F326L on NM_005996.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.298); catalogued as COSV57469685; called by muse, varscan2
- TBX4 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs755776465, COSV53605597; called by muse, mutect2
- TCP11 | c.580G>C p.G194R (on ENST00000512012; = p.G132R on NM_018679.5) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55132386; called by muse, mutect2, varscan2
- TDRD3 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52153926; called by muse, mutect2, varscan2
- TEC | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63353884; called by muse, mutect2, varscan2
- TECPR2 | c.3155C>T p.T1052I | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63969321; called by muse, mutect2, varscan2
- TECTA | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 217/252 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs544916783, COSV50690745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM2 | c.1356A>C p.E452D (on ENST00000518659 / NM_001122679.2; = p.E220D on NM_001080428.3) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1562110996, COSV69124301, COSV69136431; called by muse, mutect2, varscan2
- TERF1 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.087); catalogued as COSV52576897; called by muse, mutect2, varscan2
- TEX33 | c.493C>G p.Q165E (on ENST00000381821 / NM_001163857.2; = p.Q80E on NM_178552.4) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV67821388; called by muse, mutect2, varscan2
- TFDP2 | c.921G>C p.E307D (on ENST00000489671 / NM_001178139.2; = p.E247D on NM_006286.5) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57705700; called by muse, mutect2, varscan2
- THBS1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV52950043, COSV99527568; called by muse, mutect2
- THOC5 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63797915; called by muse, mutect2, varscan2
- THSD7A | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs900525448, COSV101448778, COSV70261183, COSV70269942; called by muse, mutect2, varscan2
- TIAM2 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150375770, COSV59688720; called by muse, mutect2, varscan2
- TIGD7 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV51915512; called by muse, mutect2
- TLN1 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59204897; called by muse, mutect2
- TLX3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs762458039, COSV51539162; called by muse, mutect2, varscan2
- TMEFF1 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV100614379; called by muse, mutect2
- TMEM258 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as rs755412184, COSV53886513, COSV53886706; called by muse, mutect2, varscan2
- TMEM68 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.155); catalogued as COSV58169786; called by muse, mutect2, varscan2
- TMTC4 | c.2128G>A p.E710K (on ENST00000376234 / NM_001350577.2; = p.E729K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.042); catalogued as COSV60891532; called by muse, mutect2
- TNFRSF8 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs754153964, COSV99821071; called by muse, mutect2, varscan2
- TNKS2 | c.1904G>A p.G635E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV65414889; called by muse, mutect2, varscan2
- TNS3 | c.2057C>G p.P686R | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV60787720; called by muse, mutect2, varscan2
- TNS3 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60787727; called by muse, mutect2, varscan2
- TOGARAM1 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61887529; called by muse, mutect2, varscan2
- TOP1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV63695089; called by muse, mutect2
- TOX3 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV54863576; called by muse, mutect2, varscan2
- TP53INP2 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66351132; called by muse, mutect2, varscan2
- TPCN1 | c.1060-1G>C p.X354_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100136396; called by muse, mutect2, varscan2
- TRANK1 | c.7386C>G p.I2462M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV57143220; called by muse, mutect2, varscan2
- TRDMT1 | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100003770, COSV100003844; called by muse, mutect2
- TRIM16L | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67459145; called by muse, mutect2, varscan2
- TRIM29 | c.1722C>G p.F574L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV59279305; called by muse, mutect2, varscan2
- TRIOBP | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as rs560619122, COSV60374416; called by muse, mutect2
- TRMT2A | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs374854124, COSV52812567; called by muse, mutect2, varscan2
- TRPM6 | c.1135-1G>A p.X379_splice | Splice Site (SNP) | VAF 29/55 reads (53%) | catalogued as COSV62504163; called by muse, mutect2, varscan2
- TTC31 | c.1549C>G p.Q517E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV99281905; called by muse, mutect2
- TTC7B | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 223/261 reads (85%) | catalogued as COSV100127255; called by muse, mutect2, varscan2
- TTLL5 | c.3418C>T p.H1140Y | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54029126; called by muse, mutect2, varscan2
- TULP4 | c.2240C>G p.S747C | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV65572910; called by muse, mutect2, varscan2
- UBA7 | c.1768G>C p.A590P | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV61091465; called by muse, mutect2
- UBQLNL | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66492772; called by muse, mutect2, varscan2
- UBR4 | c.3457G>C p.E1153Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64383825; called by muse, mutect2, varscan2
- UBR4 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs780280021, COSV64383840; called by muse, mutect2, varscan2
- UMPS | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.044); catalogued as COSV51736441; called by muse, mutect2, varscan2
- UNC80 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as COSV55884978; called by muse, mutect2, varscan2
- UNC80 | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV55886947, COSV99778400; called by muse, mutect2, varscan2
- URGCP | c.1606C>T p.R536* (on ENST00000453200 / NM_001077663.3; = p.R527* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV56245603, COSV56251886; called by muse, mutect2, varscan2
- USF1 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57036316; called by muse, mutect2, varscan2
- USP54 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60440314; called by muse, mutect2, varscan2
- UTP20 | c.3550del p.V1184Ffs*20 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | catalogued as COSV55373321; called by mutect2, pindel, varscan2
- VAPB | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV55666539, COSV55669206; called by muse, mutect2, varscan2
- VLDLR | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 214/237 reads (90%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV66073361; called by muse, mutect2, varscan2
- VPS33B | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.28); PolyPhen benign (0.287); catalogued as COSV60979239; called by muse, mutect2, varscan2
- VPS36 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV65198728; called by muse, mutect2, varscan2
- WARS2 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV52476310; called by muse, mutect2, varscan2
- WDFY3 | c.10234G>C p.E3412Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV55694967; called by muse, mutect2, varscan2
- WDFY3 | c.2177C>G p.S726* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99881928; called by muse, mutect2, varscan2
- WDR33 | c.2104C>G p.Q702E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV59246671; called by muse, mutect2, varscan2
- WDR45 | c.111G>C p.L37F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV59875542; called by mutect2, varscan2
- WNT4 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs557427439, COSV51602872; called by muse, mutect2, varscan2
- XRCC4 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.524); catalogued as rs368106955, COSV56533917, COSV56540642; called by muse, mutect2, varscan2
- ZBED4 | c.3450G>C p.M1150I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.039); catalogued as COSV53464128; called by muse, mutect2, varscan2
- ZBTB40 | c.3178G>C p.E1060Q | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as rs1476770946, COSV65144761; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54293935; called by muse, mutect2, varscan2
- ZCCHC7 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs1471485229, COSV59718751; called by muse, mutect2
- ZFAND1 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV55106893; called by muse, mutect2, varscan2
- ZFPM1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60320303; called by muse, mutect2, varscan2
- ZGPAT | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.142); catalogued as COSV100203259, COSV56648967; called by muse, mutect2, varscan2
- ZMYND8 | c.992C>G p.S331C (on ENST00000311275 / NM_001363741.2; = p.S351C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53683816; called by muse, mutect2, varscan2
- ZNF195 | c.1630C>T p.H544Y (on ENST00000399602 / NM_001130520.3; = p.H472Y on NM_007152.5) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV50002124; called by muse, mutect2, varscan2
- ZNF195 | c.1094C>T p.S365F (on ENST00000399602 / NM_001130520.3; = p.S293F on NM_007152.5) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.962); catalogued as COSV50002146; called by muse, mutect2
- ZNF208 | c.381A>C p.K127N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.337); catalogued as rs762268288, COSV68101717; called by muse, mutect2, varscan2
- ZNF354A | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV59982340; called by muse, mutect2, varscan2
- ZNF383 | c.979C>G p.Q327E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.515); catalogued as COSV61938673; called by muse, mutect2, varscan2
- ZNF519 | c.1455G>T p.E485D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV73913204; called by muse, mutect2, varscan2
- ZNF552 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV66971490; called by muse, mutect2, varscan2
- ZNF557 | c.652G>C p.V218L (on ENST00000414706 / NM_001044388.2; = p.V225L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as COSV53273104; called by muse, mutect2, varscan2
- ZNF562 | c.263C>T p.S88L (on ENST00000453372 / NM_001130032.2; = p.S16L on NM_017656.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1238442432, COSV99530508; called by muse, mutect2, varscan2
- ZNF565 | c.547G>C p.G183R (on ENST00000355114; = p.G143R on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV58410450; called by muse, mutect2, varscan2
- ZNF572 | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60001367; called by muse, varscan2
- ZNF572 | c.1568C>G p.S523C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV60001372; called by muse, varscan2
- ZNF585B | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs267605451, COSV57214743; called by mutect2, varscan2
- ZNF608 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.865); catalogued as rs1239578342, COSV60435756; called by muse, mutect2, varscan2
- ZNF622 | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58073614, COSV58074498; called by muse, mutect2
- ZNF704 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs946394280, COSV59920639; called by muse, mutect2, varscan2
- ZNF777 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs749840616, COSV56096468; called by muse, mutect2, varscan2
- ZNF804A | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100169588, COSV56438453; called by muse, mutect2
- ZRANB3 | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV51496150, COSV51504762; called by muse, mutect2, varscan2
- ZSWIM2 | c.1560G>C p.K520N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV54574122; called by muse, mutect2, varscan2
- ADAMTS7 | c.314dup p.F106Lfs*33 | Frame Shift Ins (INS) | VAF 10/16 reads (63%) | called by mutect2, pindel, varscan2
- CXCL12 | c.180-1G>C p.X60_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2
- ESYT1 | c.361dup p.Y121Lfs*20 | Frame Shift Ins (INS) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- IGHG4 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 68/120 reads (57%) | called by muse, mutect2, varscan2
- MUC17 | c.10888C>G p.P3630A | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- MUC2 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PPL | c.3910del p.T1304Pfs*8 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- SIRPD | c.116_117insTGAC p.Q39Hfs*45 | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel
- AACS | c.1650G>T p.R550= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV55534975; called by muse, mutect2, varscan2
- AAGAB | c.498G>A p.L166= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV56016038; called by muse, mutect2, varscan2
- ABCC1 | c.1536C>T p.I512= | Silent (SNP) | VAF 10/251 reads (4%) | catalogued as COSV60681614; called by muse, mutect2
- ABCC10 | c.1653C>T p.L551= (on ENST00000372530 / NM_001198934.2; = p.L508= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55085216; called by muse, mutect2, varscan2
- ABCC12 | c.3600C>T p.I1200= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV60912133; called by muse, mutect2, varscan2
- ACSF3 | c.1137G>T p.G379= | Silent (SNP) | VAF 50/358 reads (14%) | catalogued as rs755027191, COSV58077006; called by muse, varscan2
- ADA2 | c.474A>G p.K158= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV52830603; called by muse, mutect2, varscan2
- ADGRE1 | c.363C>T p.V121= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV51672790; called by muse, mutect2, varscan2
- ADHFE1 | c.639G>A p.S213= | Silent (SNP) | VAF 35/244 reads (14%) | catalogued as rs1193360767, COSV52553774; called by muse, mutect2, varscan2
- AFAP1 | c.693C>G p.V231= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV61793788, COSV61795737; called by muse, mutect2, varscan2
- AHCYL2 | c.423T>A p.R141= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV61485548; called by muse, mutect2, varscan2
- AKAP13 | c.5361G>A p.K1787= (on ENST00000394518 / NM_007200.5; = p.K1791= on NM_006738.6) | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV63450337; called by muse, mutect2, varscan2
- ANKRD13C | c.780T>C p.L260= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV52029454; called by muse, mutect2
- APOB | c.2283G>C p.L761= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV51926114; called by muse, mutect2, varscan2
- ARAP2 | c.847C>T p.L283= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV58283546; called by muse, mutect2, varscan2
- AREL1 | c.1647G>C p.L549= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV62665657; called by muse, mutect2, varscan2
- ASCC3 | c.3201A>T p.R1067= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV61226307; called by muse, mutect2, varscan2
- AUTS2 | c.3718C>T p.L1240= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV61386755; called by muse, mutect2, varscan2
- AVPR1B | c.1191C>T p.L397= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV65637797; called by muse, mutect2, varscan2
- BCO2 | c.1701G>A p.Q567= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV63062724; called by muse, mutect2, varscan2
- BTNL3 | c.918G>A p.L306= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100732169, COSV61565372; called by muse, mutect2, varscan2
- C1RL | c.357G>A p.L119= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as COSV99864407; called by muse, mutect2, varscan2
- C20orf96 | c.591G>A p.L197= (on ENST00000360321 / NM_153269.3; = p.L196= on NM_080571.1) | Silent (SNP) | VAF 42/253 reads (17%) | catalogued as COSV64403137; called by muse, mutect2, varscan2
- C2orf78 | c.1263G>A p.K421= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1274285368, COSV68516621; called by muse, mutect2, varscan2
- C4B | c.3369G>A p.V1123= | Silent (SNP) | VAF 75/108 reads (69%) | catalogued as rs371168662; called by muse, mutect2, varscan2
- CAPN11 | c.1506C>T p.F502= | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as COSV67236399; called by muse, mutect2, varscan2
- CAPZA3 | c.114C>A p.I38= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV56849793; called by muse, mutect2
- CARD10 | c.1905G>A p.R635= | Silent (SNP) | VAF 54/263 reads (21%) | catalogued as rs1436322869, COSV52654788; called by muse, varscan2
- CARMIL1 | c.2379G>A p.V793= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV61514551; called by muse, mutect2, varscan2
- CBR3 | c.807C>G p.V269= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV51740816; called by muse, mutect2
- CCDC88A | c.2214G>A p.K738= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV55057756, COSV55060112; called by muse, mutect2, varscan2
- CDON | c.1425C>T p.F475= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs768862954, COSV54995704; called by muse, mutect2, varscan2
- CEMIP | c.1488G>T p.R496= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV54989031; called by muse, mutect2, varscan2
- CFAP45 | c.243C>A p.L81= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as COSV63648261; called by muse, mutect2, varscan2
- CHFR | c.1059C>T p.H353= (on ENST00000432561 / NM_001161345.1; = p.H312= on NM_018223.2) | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV57172558; called by muse, mutect2, varscan2
- CLCN1 | c.705C>T p.F235= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs760323048, COSV100578290, COSV58367907; called by muse, mutect2, varscan2
- CROCC | c.3579G>A p.V1193= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100978048; called by muse, mutect2
- CTSA | c.114C>A p.L38= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV51940921; called by muse, mutect2, varscan2
- CYP2A7 | c.471C>T p.I157= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs534396743, COSV52498541; called by muse, mutect2, varscan2
- CYP7A1 | c.741C>G p.L247= | Silent (SNP) | VAF 45/282 reads (16%) | catalogued as COSV56962651; called by muse, mutect2, varscan2
- DCLRE1A | c.1317A>G p.Q439= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1200421782, COSV63748252; called by muse, mutect2, varscan2
- DDX19A | c.259C>T p.L87= | Silent (SNP) | VAF 38/185 reads (21%) | catalogued as rs372457359; called by muse, mutect2, varscan2
- DEPTOR | c.171C>G p.L57= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs752543031, COSV53813254, COSV53822466; called by muse, mutect2, varscan2
- DICER1 | c.5295C>G p.L1765= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58616356, COSV58620110; called by muse, mutect2, varscan2
- DNAH2 | c.5862G>A p.K1954= | Silent (SNP) | VAF 11/176 reads (6%) | catalogued as COSV66717283; called by muse, mutect2
- DNAH3 | c.10038C>T p.I3346= | Silent (SNP) | VAF 183/290 reads (63%) | catalogued as COSV54501104, COSV99769903; called by muse, mutect2, varscan2
- DNAH3 | c.9831G>A p.Q3277= | Silent (SNP) | VAF 26/346 reads (8%) | catalogued as COSV54507518; called by muse, mutect2
- EFNB1 | c.768C>T p.I256= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as rs763308440, COSV52661132; called by muse, mutect2, varscan2
- EFS | c.108G>A p.Q36= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53731404; called by muse, mutect2, varscan2
- EMCN | c.780G>A p.K260= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV56457094, COSV56457800; called by muse, mutect2, varscan2
- EVC2 | c.1185G>C p.L395= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV60388697, COSV60390121; called by muse, mutect2
- EXOSC10 | c.1494G>A p.Q498= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV58664082; called by muse, mutect2, varscan2
- EXTL3 | c.570C>T p.L190= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV55036997; called by muse, mutect2
- FAM120A | c.636C>T p.L212= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs775364206, COSV52901973; called by muse, mutect2, varscan2
- FAM193A | c.150C>G p.T50= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV100218526; called by muse, mutect2
- FAM193A | c.3147G>A p.L1049= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV61191745; called by muse, mutect2, varscan2
- FAM207A | c.441C>T p.L147= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99384212, COSV99384229; called by muse, mutect2
- FAM78B | c.330G>A p.V110= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs748492887, COSV57975607; called by muse, mutect2, varscan2
- FAT1 | c.7485C>T p.N2495= | Silent (SNP) | VAF 107/249 reads (43%) | catalogued as rs775884355, COSV71671621; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLRT2 | c.762G>A p.L254= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs932694309, COSV58137397; called by muse, mutect2, varscan2
- FSD2 | c.786C>T p.I262= | Silent (SNP) | VAF 97/100 reads (97%) | catalogued as COSV58008928; called by muse, mutect2, varscan2
- FUT3 | c.768C>T p.I256= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as COSV54604802; called by muse, mutect2, varscan2
- GABRQ | c.735G>C p.V245= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV64781053; called by muse, mutect2
- GHRHR | c.691C>T p.L231= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV58195741, COSV58196214; called by muse, mutect2, varscan2
- GPHB5 | c.214C>T p.L72= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100030142; called by muse, mutect2, varscan2
- GPR75 | c.273C>G p.L91= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100766283, COSV61825338; called by muse, mutect2, varscan2
- GRIA1 | c.501G>A p.E167= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV53591894; called by muse, mutect2, varscan2
- GXYLT2 | c.1206T>C p.F402= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV67473578; called by muse, mutect2, varscan2
- GZF1 | c.1248G>C p.L416= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV57635107; called by muse, mutect2, varscan2
- H1-5 | c.273G>C p.V91= | Silent (SNP) | VAF 42/251 reads (17%) | catalogued as COSV58899251; called by muse, mutect2, varscan2
- H3C2 | c.354G>C p.V118= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV52518001, COSV52519340; called by muse, mutect2, varscan2
- HCN3 | c.1437C>T p.G479= | Silent (SNP) | VAF 34/233 reads (15%) | catalogued as rs776411741, COSV61360588; called by muse, mutect2, varscan2
- HMCN1 | c.2829G>A p.G943= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV54882265; called by muse, mutect2, varscan2
- IFNL1 | c.237G>C p.L79= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV61317557; called by muse, mutect2, varscan2
- IFT172 | c.3159C>G p.L1053= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV53130897; called by muse, mutect2, varscan2
- IGHG4 | c.195C>T p.L65= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- IGKV3-7 | c.93G>C p.L31= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- IL4R | c.1662C>T p.L554= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99405055; called by muse, mutect2
- IMPDH1 | c.1541G>A p.*514= (on ENST00000470772 / NM_001142573.2; = p.*600= on NM_000883.4) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100118583; called by muse, mutect2, varscan2
- IPO13 | c.1446C>T p.V482= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV64893900, COSV64894157; called by muse, mutect2, varscan2
- IQSEC1 | c.741G>A p.V247= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV56221745; called by muse, mutect2, varscan2
- IRS2 | c.2760C>T p.I920= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV101018798; called by muse, mutect2
- ITGA9 | c.672G>T p.L224= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as COSV53237458; called by muse, mutect2, varscan2
- KATNAL1 | c.735G>A p.L245= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV66062746; called by muse, mutect2, varscan2
- KCNH8 | c.864C>T p.I288= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV60458002; called by muse, mutect2, varscan2
- KCNJ15 | c.792G>A p.L264= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100154097, COSV60810374; called by muse, mutect2, varscan2
- KDM4A | c.1534C>T p.L512= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV64958955; called by muse, mutect2, varscan2
- KMT2B | c.4749C>G p.L1583= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs746970119, COSV55858103, COSV55863777; called by muse, mutect2, varscan2
- KRT39 | c.669G>C p.L223= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV62916911; called by muse, mutect2, varscan2
- LAMA2 | c.2058A>G p.L686= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs1044635780, COSV70340647; called by muse, mutect2, varscan2
- LGALSL | c.162G>A p.V54= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs767358236, COSV53230117; called by muse, mutect2, varscan2
- LIAS | c.447G>A p.R149= (on ENST00000261434 / NM_001363700.2; = p.R252= on NM_006859.4) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54695044; called by muse, mutect2, varscan2
- LILRA5 | c.846G>C p.L282= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1482944414, COSV56641845; called by muse, mutect2, varscan2
- LILRB2 | c.178C>T p.L60= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV58743861; called by muse, mutect2
- LIMCH1 | c.1608G>C p.L536= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs141526843; called by muse, mutect2, varscan2
- LRPPRC | c.3318C>T p.A1106= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV53234935; called by muse, mutect2, varscan2
- LRRC15 | c.1320C>T p.L440= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1226666340, COSV61649611; called by muse, mutect2, varscan2
- LRRC8A | c.1992G>A p.L664= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV52183704, COSV52184436; called by muse, mutect2, varscan2
- LRRK2 | c.7005C>T p.L2335= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs771244881, COSV100109441, COSV54146278; called by muse, mutect2, varscan2
- MACF1 | c.4917G>A p.V1639= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV57109705; called by muse, mutect2, varscan2
- MAST4 | c.4596G>A p.L1532= (on ENST00000403625 / NM_001164664.2; = p.L1343= on NM_015183.3) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55117832; called by muse, mutect2, varscan2
- MED12L | c.4656T>G p.T1552= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV56370921; called by muse, mutect2, varscan2
- MIOS | c.1269C>G p.L423= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV60767316; called by muse, mutect2, varscan2
- NAA11 | c.150G>A p.G50= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs1219953437, COSV54514047; called by muse, mutect2, varscan2
- NAXD | c.702C>T p.L234= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV59393728; called by muse, mutect2, varscan2
- NCKAP1L | c.1704C>T p.F568= | Silent (SNP) | VAF 42/209 reads (20%) | catalogued as rs148042893; called by muse, mutect2, varscan2
- NECTIN3 | c.1503C>G p.L501= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV60550158; called by muse, mutect2, varscan2
- NPY5R | c.978C>A p.S326= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58451232; called by muse, mutect2, varscan2
- NTS | c.51C>T p.F17= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs892262829, COSV55455594; called by muse, mutect2, varscan2
- NUDC | c.312C>T p.I104= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1314407487, COSV58324738; called by muse, mutect2
- NUP62 | c.711C>G p.L237= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs1264925278, COSV61311113; called by muse, mutect2, varscan2
- OPALIN | c.285G>A p.T95= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs183417445, COSV64520392; called by muse, mutect2, varscan2
- OR13C2 | c.135C>T p.L45= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV101604854; called by muse, mutect2, varscan2
- OR2G3 | c.279T>G p.T93= | Silent (SNP) | VAF 31/268 reads (12%) | catalogued as COSV60680716, COSV60681025; called by muse, mutect2, varscan2
- OR4N2 | c.612C>T p.G204= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as rs781326367, COSV60050293; called by muse, mutect2, varscan2
- OR8H2 | c.843G>A p.V281= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV57943516; called by muse, mutect2, varscan2
- PA2G4 | c.213G>A p.K71= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1431723941, COSV57248034; called by muse, varscan2
- PATZ1 | c.1809G>A p.K603= | Silent (SNP) | VAF 33/654 reads (5%) | catalogued as COSV56742984; called by muse, mutect2
- PCSK5 | c.855C>T p.A285= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as rs1433014446, COSV65084731; called by muse, mutect2, varscan2
- PEG3 | c.4041C>G p.L1347= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV55627217; called by muse, mutect2, varscan2
- PIKFYVE | c.3711C>T p.V1237= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52237942; called by muse, mutect2, varscan2
- PIP4K2A | c.807G>A p.L269= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1359111787, COSV60540169; called by muse, mutect2, varscan2
- PKD1 | c.8088C>T p.L2696= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs752542616, COSV99237114; called by muse, mutect2, varscan2
- PLAUR | c.123G>C p.L41= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV55388810; called by muse, mutect2, varscan2
- PLCXD1 | c.363C>T p.V121= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs1283508298, COSV67541555; called by muse, mutect2
- PNKP | c.528C>G p.L176= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV55586478, COSV55586605; called by muse, mutect2, varscan2
- PODNL1 | c.468C>G p.L156= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54308031; called by muse, mutect2, varscan2
- POLR1A | c.4440G>T p.L1480= | Silent (SNP) | VAF 61/161 reads (38%) | catalogued as COSV55690019, COSV55695266; called by muse, mutect2, varscan2
- POU4F1 | c.1152G>A p.K384= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV65883867; called by muse, mutect2, varscan2
- PRICKLE1 | c.1066C>T p.L356= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV61542178; called by muse, mutect2, varscan2
- PRKCB | c.1269G>C p.V423= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV57769239; called by muse, mutect2, varscan2
- PRPF19 | c.225G>A p.L75= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as COSV57127102; called by muse, mutect2, varscan2
- PSD3 | c.1755C>T p.A585= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs749742474, COSV54067510; called by muse, mutect2, varscan2
- ROBO4 | c.42C>T p.S14= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV60621923; called by muse, mutect2, varscan2
- RTTN | c.2214C>T p.L738= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV55342084, COSV99733912; called by muse, mutect2, varscan2
- SAMD9L | c.4377C>T p.F1459= | Silent (SNP) | VAF 52/77 reads (68%) | catalogued as COSV59080080; called by muse, mutect2, varscan2
- SEMA5A | c.3015C>T p.V1005= | Silent (SNP) | VAF 61/254 reads (24%) | catalogued as COSV66786211; called by muse, mutect2, varscan2
- SLC35F3 | c.609C>T p.F203= (on ENST00000366617 / NM_001300845.1; = p.F272= on NM_173508.4) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV64018367; called by muse, mutect2, varscan2
- SLC39A12 | c.777C>T p.L259= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as COSV66195785; called by muse, mutect2, varscan2
- SLC9A7 | c.465G>A p.L155= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV60378333; called by muse, mutect2, varscan2
- SLC9A8 | c.1053C>A p.L351= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as COSV64287406; called by muse, mutect2, varscan2
- SMARCA1 | c.1062C>G p.L354= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100946564, COSV64411091; called by muse, mutect2, varscan2
- SPATA4 | c.639C>G p.L213= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV54589018; called by muse, mutect2, varscan2
- SPNS1 | c.874C>T p.L292= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV57953859; called by mutect2, varscan2
- SULT4A1 | c.18C>A p.A6= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV50780452; called by muse, mutect2, varscan2
- SUMF1 | c.258C>T p.L86= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99794441; called by muse, varscan2
- SUN1 | c.1446G>A p.L482= (on ENST00000405266 / NM_001367651.1; = p.L362= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs757133113, COSV61777552; called by muse, mutect2, varscan2
- SYNE1 | c.25821C>T p.L8607= (on ENST00000367255 / NM_182961.4; = p.L8559= on NM_033071.3) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99552611; called by muse, mutect2
- TAAR1 | c.126G>C p.L42= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV51587843; called by muse, mutect2, varscan2
- TAS1R1 | c.2301C>G p.L767= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV59839452; called by muse, mutect2, varscan2
- TEP1 | c.7842G>C p.V2614= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV52989036; called by muse, mutect2, varscan2
- THAP9 | c.2232C>G p.L744= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV56355818; called by muse, mutect2, varscan2
- TICRR | c.1525T>C p.L509= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as COSV51538662; called by muse, mutect2, varscan2
- TICRR | c.2730C>G p.T910= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV51538670; called by muse, mutect2, varscan2
- TIMELESS | c.1014G>C p.V338= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV57509543; called by muse, varscan2
- TLR5 | c.870G>A p.V290= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV60558147; called by muse, mutect2, varscan2
- TMC3 | c.1872C>G p.L624= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as COSV63922413; called by muse, mutect2, varscan2
- TMEM131 | c.4014G>A p.A1338= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs762695162, COSV51771269; called by muse, varscan2
- TMTC2 | c.2510G>A p.*837= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100337537; called by muse, mutect2, varscan2
- TRO | c.1704G>A p.V568= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as rs1046829668, COSV51498392; called by muse, varscan2
- TTN | c.78192C>T p.P26064= (on ENST00000591111; = p.P18640= on NM_003319.4) | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs747021593, COSV59917757, COSV59932766; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTYH1 | c.1352G>A p.*451= | Silent (SNP) | VAF 13/218 reads (6%) | catalogued as COSV56609994; called by muse, mutect2
- UBR4 | c.11121A>G p.K3707= | Silent (SNP) | VAF 75/223 reads (34%) | catalogued as COSV64383811; called by muse, mutect2, varscan2
- UGT2B15 | c.1299C>G p.V433= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as COSV100592395, COSV57733274; called by muse, mutect2, varscan2
- UMOD | c.963C>T p.F321= | Silent (SNP) | VAF 57/277 reads (21%) | catalogued as COSV56774112; called by muse, mutect2, varscan2
- UNC45A | c.2700G>C p.L900= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV67793503; called by muse, mutect2, varscan2
- USP19 | c.324C>G p.L108= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV59731419; called by muse, mutect2, varscan2
- USP4 | c.249G>A p.L83= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV55535274; called by muse, mutect2, varscan2
- VPS36 | c.891G>C p.L297= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV65198733; called by muse, mutect2, varscan2
- WDR26 | c.2157G>A p.V719= (on ENST00000414423 / NM_001379403.1; = p.V619= on NM_025160.7) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV54353573; called by muse, mutect2, varscan2
- WDR37 | c.831C>T p.L277= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV54127325; called by muse, mutect2, varscan2
- WWC1 | c.585G>A p.L195= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99514179; called by muse, mutect2
- XIRP1 | c.2184C>T p.F728= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV61137305; called by muse, mutect2, varscan2
- XPR1 | c.1215G>C p.V405= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV62554774, COSV62555901; called by muse, mutect2, varscan2
- ZFAND4 | c.711C>T p.S237= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV60857924; called by muse, mutect2, varscan2
- ZNF195 | c.1845C>T p.F615= (on ENST00000399602 / NM_001130520.3; = p.F543= on NM_007152.5) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99137586; called by muse, varscan2
- ZNF519 | c.345G>T p.V115= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV73913205; called by muse, mutect2, varscan2
- ZNF543 | c.1650C>T p.L550= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs549745000, COSV58626588; called by muse, mutect2, varscan2
- ZNF687 | c.3645C>G p.L1215= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV55015650; called by muse, mutect2, varscan2
- ZNF746 | c.810G>A p.L270= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV61406572; called by muse, mutect2, varscan2
- ZNF750 | c.510C>G p.L170= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV53958782; called by muse, mutect2, varscan2
- ZNF75D | c.813C>T p.V271= | Silent (SNP) | VAF 25/632 reads (4%) | catalogued as COSV66132444; called by muse, mutect2
- ZNF75D | c.18G>A p.L6= | Silent (SNP) | VAF 39/900 reads (4%) | catalogued as COSV66132449; called by muse, mutect2
- ZP2 | c.627C>G p.L209= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as COSV54812498; called by muse, mutect2
- AL163540.1 | n.33G>T | RNA (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- CATSPERD | c.-1G>C | 5'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100638513; called by muse, varscan2
- DIRC1 | n.398G>A | RNA (SNP) | VAF 25/35 reads (71%) | catalogued as COSV57365865, COSV57370280; called by muse, mutect2, varscan2
- ECPAS | chr9:111484738 G>C | 5'Flank (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99397467; called by muse, mutect2, varscan2
- H3-4 | c.-1C>T | 5'UTR (SNP) | VAF 14/74 reads (19%) | catalogued as rs200747237; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407803 G>A | 5'Flank (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56678514; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331573 C>G | 5'Flank (SNP) | VAF 6/76 reads (8%) | catalogued as COSV59807586, COSV59810851; called by muse, mutect2
- MACF1 | c.15832-11176G>A | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as rs1173510609, COSV99241079; called by muse, mutect2
- PCSK5 | c.2626+3540G>C | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as COSV65084742, COSV65088942; called by muse, mutect2, varscan2
- RASSF1 | c.369+624G>A | Intron (SNP) | VAF 19/121 reads (16%) | catalogued as COSV51600006; called by muse, mutect2, varscan2
7 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 7 other) are not listed here.
